CCDI case PBBLXR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Nasopharynx.
https://portal.gdc.cancer.gov/cases/2785946b-f8ed-420a-b7f5-03784544f31f

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Nasopharynx, NOS; Age at diagnosis: 3.3 years (1,205 days).

Biospecimens (4 samples)
- Sample 0DCWB3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DCWB8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Samples 0DCWBE, 0DCYNJ (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
